Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-7923, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-7923-01A (Primary Tumor).

[page 1 of 4]
Patient Results

Surgical Pathology (Copath)

Final

Path Report

Final

SURGICAL PATHOLOGY REPORT

ACCESSION NO. [REDACTED]

Final Diagnosis(es):

(A) Lymph node, hepatoduodenal, biopsy: One lymph node, negative for malignancy (0/1).

(B) Lymph node, posterior portal, biopsy: One lymph node, negative for malignancy (0/1).

(C) Bile duct margin, biopsy: Negative for malignancy.

(D) Pancreatic gland margin, excision:

1) Small fragment of pancreatic tissue with chronic pancreatitis.

2) One lymph node, negative for malignancy (0/1).

(E) Pancreatic duct margin, biopsy: Negative for malignancy.

(F) Head of pancreas, stomach, duodenum, pancreaticoduodenectomy (Whipple procedure):

1) Ductal adenocarcinoma of the pancreas.

2) Tumor size: 3.0 cm in greatest dimension.

3) All margins are negative for involvement by carcinoma.

4) Fourteen lymph nodes, negative for malignancy (0/14).

5) The tumor involves the ampulla of Vater (duodenum).

6) Pathologic staging: pT3N0.

7) See Synoptic Report below for complete tumor summary.

8) Stomach with no histopathologic abnormality.

Synoptic Report:

Specimen:

Head of pancreas.

Duodenum.

Stomach.

Common bile duct.

Procedure: Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy.

Tumor Site: Pancreatic head.

Tumor Size:

Greatest Dimension: 3.0 cm.

Additional Dimensions: 2.5 x 1.5 cm.

Histologic Type: Ductal adenocarcinoma.

Histologic Grade: G2: Moderately differentiated.

Microscopic Tumor Extension: Tumor invades ampulla of Vater.

Margins: Margins uninvolved by invasive carcinoma.

Treatment Effect: Not known.

Lymphovascular Invasion: Not identified.

Perineural Invasion: Not identified.

Pathologic Staging:

Primary Tumor: pT3: tumor extends beyond the pancreas but without involvement of the celiac

axis or the superior mesenteric artery.

Regional Lymph Nodes: pN0: No regional lymph node

Printed from: Default

[page 2 of 4]
Patient Results

Surgical Pathology (Copath)

Final

metastasis.

Number of Lymph Nodes Examined: 17

Number of Lymph Nodes Involved: 0

Distant Metastasis: Not applicable.

Additional Pathologic Findings: Pancreatic intraepithelial neoplasia (highest grade: PanIN 3).

Chronic pancreatitis.

Comments:

This case has been reviewed and the diagnosis approved by consulting departmental surgical pathology staff.

'The gross description and all microscopic slides have been reviewed and interpreted by the undersigned pathologist'

Specimen(s) Received:

A: Hepatoduodenum

B: Posterior portal lymph node

C: Bile duct margin

D: Pancreatic gland

E: Pancreatic duct

F: Small bowel, head of pancreas, stomach, duodenum

Clinical History:

Pancreatic cancer.

Intraoperative Consultation:

Time Received:

Time Reported:

FSC1: Bile duct margin: Negative, concurs (1 block).

FSD1: Pancreas gland margin: Negative, (1 block).

FSE1: Pancreatic duct margin: Negative, (1 block).

Gross Description:

(A) (hepatoduodenum) Received in formalin is a portion of rubbery tan-brown soft tissue, consistent with lymph node, with attached yellow tan fibrofatty tissue measuring 1.0 x 1.0 x 0.5 cm in greatest dimensions. The specimen is entirely submitted in toto in mesh cassette A1.

(B) (posterior portal lymph node) Received in formalin is a portion of rubbery red- tan soft tissue, consistent with lymph node, measuring 0.6 x 0.3 x 0.2 cm in greatest dimensions. The specimen is entirely submitted in cassette B1.

(C) (bile duct margin, suture true margin) Received fresh from

[page 3 of 4]
[REDACTED]

Patient Results

[REDACTED]

[REDACTED] Surgical Pathology (Copath) [REDACTED]

Final

the OR for frozen section to evaluate for malignancy is shaved portion of bile duct which measures 1.5 x 1.0 x 0.5 cm in greatest dimensions. The entire specimen is frozen and then submitted for permanent section in cassette FSC1.

(D) (pancreatic gland) Received fresh from the OR for frozen section to evaluate for malignancy is a portion of red-yellow soft tissue which measures 2.0 x 0.8 x 0.3 cm in greatest dimensions. The suture is placed on the true margin. The true margin is submitted for frozen section and then submitted for permanent section in cassette FSD1. The remaining tissue is submitted in cassette D2.

(E) (pancreatic duct, stitch marks true margin) Received fresh from the OR for frozen section to evaluate for malignancy is a circular portion of red-white which measures 1.0 x 1.0 x 0.3 cm in greatest dimensions. The specimen is entirely submitted for frozen section and then submitted for permanent section in cassette FSE1.

(F) (gallbladder, small bowel, head of pancreas, stomach, duodenum) Received in formalin is a portion of small bowel, head of the pancreas, and stomach. The entire specimen measures 25.0 cm in length, 14.0 cm in width and 3.0 cm in the anteroposterior dimension. The stomach measures 10.0 cm in length and 12.0 cm in open circumference. The small bowel measures 20.0 cm in length and 7.0 cm in open circumference. The head of the pancreas measures 3.0 cm x 3.0 cm x 1.5 cm in greatest dimensions. The specimen is inked as follows: Anterior surface - yellow, pancreatic duct margin - red, posterior surface - black, bile duct margin - blue, vascular margin - indigo, bile duct after opening the specimen - orange, and uncus margin - green. The specimen is opened through ampulla and reveals an ill-defined, white, firm mass measures 3.0 x 2.5 x 1.5 cm in greatest dimensions. The mass completely involves the head of pancreas, encases the bile duct and is grossly present at the uncus and posterior retroperitoneal margins. Dissection of the adjacent fat reveals a total of 18 lymph nodes, ranging in size from 0.2 to 0.8 cm in greatest diameter. The gallbladder mentioned on the requisition and on the container is not present. Blocks are submitted as follows:

F1 - gastric margin

F2 - small bowel margin

F3-F4 - uncus margin perpendicularly sectioned and submitted into cassettes

F5 - bile duct margin en face

F6 - posterior retroperitoneal margin

F7 - pancreatic duct margin

F8 - anterior retroperitoneal margin

F9-F10 - section of the duodenal bulb, ampulla, bile duct and tumor

F11-F12 - the vascular margin perpendicularly sectioned

[page 4 of 4]
[REDACTED]

Patient Results

[REDACTED]

Surgical Pathology (Copath)

Final

F13-F15 - representative section of tumor
F16 - representative section of the normal looking stomach and duodenum
F17 - section from the duodenum near the ampulla with indented mucosal surface
F18-F20 - six lymph nodes each

[REDACTED]

Microscopic Description:

Complete microscopic evaluation has been performed. [REDACTED]

Appropriately reacting controls have been performed and evaluated for all stains on this case as required.

Histopathology has a list of IH antibodies that are regulated as analyte specific reagents (ASR's). These assays were developed and their performance characteristics determined by the Histopathology Laboratory in the Department of Pathology at the [REDACTED]. They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary for the ASR's. These tests are not investigational and are used in standard clinical care. In cases where Immunohistochemistry testing is performed, the following antibodies and their respective clones may be used to determine therapy for the patient: EFGR(31G7), ER(SP1), PR(1E2), Her2neu(4B5), CD117(Poly), CD20(L26).

Unless otherwise stated in the report, all tissue tested for ERPR by IHC, Her2 by IHC and/or HER2 by FISH have been fixed as per ANP.22998 for a minimum of 6 hours and a maximum of 48 hours.

ER, PR, Ki-67, p53 are reported as a semi-quantitative percentage of positively stained nuclei. Her-2/neu and EGFR are scored as follows: No staining at all is scored as (0), weak, incomplete membrane staining in any proportion of cells is scored as (1+), less than strong but complete staining in any proportion of cells or complete strong staining in less than 30% of cells is scored as (2+), and strong complete staining in more than 30% of cells is scored as (3+). All studies are performed on tissue fixed in 10% neutral buffered formalin and embedded in paraffin unless otherwise stated in the report.

Source: NCI Genomic Data Commons file d001b41a-53e2-48cf-b022-e6c5b8bd14b1 (TCGA-HZ-7923.17AC260A-9A9A-4F64-BD00-9A54716911DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).